Somatic mutation profile of tumor specimen BLGSP-71-06-00161-01A (aliquot BLGSP-71-06-00161-01A-01D-A512-33) from CGCI case BLGSP-71-06-00161, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.1 years (2,946 days).
Specimen BLGSP-71-06-00161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2edca6e2-a91f-4a8d-b3a9-8c02f15e3418.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00161-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00161-12A-01D-A512-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04bd7e2e-bc56-4e2f-80f3-b075263a22a6

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>A p.X307_splice | Splice Site (SNP) | VAF 41/209 reads (20%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTK | c.1000T>G p.Y334D | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM057430; called by muse, mutect2
- MYC | c.445C>G p.L149V (on ENST00000377970; = p.L164V on NM_002467.6) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV52367523, COSV99420475; called by muse, mutect2, varscan2
- BTK | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 23/304 reads (8%) | called by muse, mutect2
